Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A25Y, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A25Y-01A (Primary Tumor).

[page 1 of 3]
LABORATORY SERVICES

ICD-0-3
carcinoma, hepatocellular, NOS 8170/3
Site: Liver c22.0 for
4/25/11

Accession #:
Name:
Patient ID:
PHN:
ALT ID:
DOB:
Telephone:
Requesting Physician:
Encounter:
Chart ID:

UUID: SAEF060-BA18-416A-8E3F-604891A9A6D2

HISTOPATHOLOGY REPORT

Division Head:

Inquiry Numbers:

ORIGINAL REPORT

SPECIMEN:

- A. Gallbladder
- B. Liver (margin painted black - a slice of tumor about 0.3 cm thick was taken for tumor bank - Dr. research)

CLINICAL HISTORY:

Liver mass. Hep B positive and liver tumor.

DIAGNOSIS:

A. GALLBLADDER:

- NO CALCULI, INFLAMMATION OR MALIGNANCY.

B. LIVER:

- HEPATOCELLULAR CARCINOMA, GRADE III/IV.
- TUMOR MEASURES 2.5 CM IN GREATEST DIMENSION.
- TUMOR IS SOLITARY WITH NO SATELLITE NODULES IDENTIFIED.
- TUMOR COMPRESSES, BUT DOES NOT APPEAR TO INVADE THROUGH LIVER CAPSULE.
- RESECTION MARGIN IS CLEAR OF TUMOR, WITH CLOSEST TUMOR BEING 1.0 CM AWAY FROM MARGIN.
- NO VASCULAR INVASION IS IDENTIFIED.
- UNINVOLVED HEPATIC PARENCHYMA SHOWS MODERATE STEATOSIS, CHRONIC HEPATITIS AND PERIportal FIBROSIS (GRADE III, STAGE 2).

Reported:

Reported by:

Signed by:

(Electronic Signature)

FINAL

Page 1 *** CONTINUED

[page 2 of 3]
LABORATORY SERVICES

Accession #:
Name:
Patient ID:
PHN:
ALT ID:
DOB:
Telephone:
Requesting Physician:
Encounter:
Chart ID:

HISTOPATHOLOGY REPORT

Division Head:

Inquiry Numbers:

GROSS DESCRIPTION:

A. The specimen consists of an intact gallbladder measuring 8.3 x 2.4 x 2.6 cm. The serosal surface is smooth. The lumen contains green bile and no calculi, and the cystic duct is patent. The mucosa is granular, and the wall averages 0.2 cm in thickness. The cystic duct lymph node is not identified. Representative sections are submitted in one cassette.

PLEASE NOTE: There is also a 0.5 cm polyp identified on the mucosa which has been sampled in the cassette.

B. The specimen is received fresh and is submitted in formalin. The specimen consists of a segment of liver measuring 13 x 6.9 x 3.7 cm. The resection margin is dyed with black ink. Grossly on the liver surface, there is a grossly identifiable light tan nodule which grossly appears to invade the liver capsule. Upon sectioning through this portion, there is a grossly identifiable tumor measuring 2.5 x 2.2 x 2.1 cm. This lesion has a nodular appearance and comes to within 1.0 cm of the surgical resection margin. The remainder of the specimen is sectioned and reveals no more gross abnormalities. Representative sections of the tumor including the grossly deepest point of invasion to the resection margin and the invasion to the liver capsule are submitted in blocks B1 to B5. Representative sections of grossly unremarkable liver parenchyma are submitted in block B6.

MICROSCOPIC DESCRIPTION:

The gallbladder wall appears thin. The mucosa shows a polypoid lesion consisting of aggregates of foamy histiocytes covered by intact mucosa, consistent with a cholesterol polyp. There is no dysplasia. No significant inflammation is present. The cystic duct is unremarkable.

The liver mass shows features of a hepatocellular carcinoma. The tumor has a lobulated border with the adjacent hepatic parenchyma. The tumor cells are arranged in solid sheets, acinar formations and trabeculae. Their cytoplasm varies from eosinophilic to clear, and the nuclei show moderate to severe cytologic atypia, with some areas of the tumor demonstrating marked nuclear pleomorphism and prominent mitotic activity. Coarse fibrous septae are noted between the lobules of tumor, but no satellite nodules are noted in the adjacent parenchyma. No vascular invasion is identified. The adjacent parenchyma shows moderate microvesicular and macrovesicular steatosis and evidence of chronic hepatitis, including chronic portal inflammation with interface hepatitis, and lobular inflammation with hepatocyte dropout. There is also anisocytosis and anisonucleosis. Trichrome stain reveals evidence of periportal fibrosis with some bridging, but no evidence of established

[page 3 of 3]
LABORATORY SERVICES

Accession #:
Name:
Patient ID:
PHN:
ALT ID:
DOB:
Telephone:
Requesting Physician:
Encounter:
Chart ID:

HISTOPATHOLOGY REPORT

Division Head: Dr.

Inquiry Numbers:

MICROSCOPIC DESCRIPTION:
cirrhosis.

Immunohistochemistry was performed on the tumor and reveals it to be positive for CAM 5.2, HEP PAR-1 (patchy) and alpha fetoprotein (focal); there is very weak/equivocal staining with cytokeratin 7 and no staining with cytokeratin 20, synaptophysin or TTF1 (non-specific cytoplasmic staining only).

Procedure:

FINAL

Page 3 * END OF REPORT *

Source: NCI Genomic Data Commons file 3738f46b-742e-4b31-8c34-f029222350fe (TCGA-G3-A25Y.5AEEF060-BA18-416A-BE3F-604891A9A6D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).